Gene-level copy-number profile of tumor specimen HTMCP-01-06-00227-01A from CGCI case HTMCP-01-06-00227, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.6 years (2,758 days).
Specimen HTMCP-01-06-00227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 02852bf2-6ac5-4919-ae88-34266ecc9684.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00227-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/6e1d036a-4f0c-49d1-88ab-53e8e44ad008

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 3,088; copy number 2: 55,328; copy number 3: 417.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,269,140, 80 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
